Somatic mutation profile of tumor specimen BA2688D (aliquot aq-BA2688D) from BEATAML1.0 case 2289, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute erythroid leukaemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 53.6 years (19,582 days).
Specimen BA2688D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9ec27056-dbc7-4ecc-a63c-a2c13da81baf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2833D (Solid Tissue Normal), aliquot aq-BA2833D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b2770235-22ee-4e0a-9a84-840af101ef96

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 8, Silent 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNMT3A | c.2644C>T p.R882C | Missense Mutation (SNP) | VAF 30/81 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs377577594, COSV53036332, COSV53037241, COSV53063308; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- EPHA7 | c.2530G>T p.D844Y | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65182470; called by muse, mutect2, varscan2
- TTN | c.69248C>T p.T23083I (on ENST00000591111; = p.T15659I on NM_003319.4) | Missense Mutation (SNP) | VAF 45/137 reads (33%) | PolyPhen benign (0.427); catalogued as rs528199512; called by muse, mutect2, varscan2
- AAR2 | c.357C>A p.D119E | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ENTR1 | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- FAM229A | c.34G>T p.A12S | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.066); called by muse, mutect2
- KALRN | c.1271C>A p.A424D | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NPR3 | c.1103A>G p.Y368C | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); called by mutect2, varscan2
- WT1 | c.1063-5_1069del p.X355_splice | Splice Site (DEL) | VAF 27/211 reads (13%) | called by mutect2, pindel, varscan2
- ARHGAP20 | c.1473G>T p.V491= | Silent (SNP) | VAF 6/92 reads (7%) | called by muse, mutect2
- BCOR | c.1635G>T p.P545= | Silent (SNP) | VAF 6/118 reads (5%) | called by muse, mutect2
- LETM2 | c.1101G>A p.T367= (on ENST00000379957 / NM_001286819.2; = p.T272= on NM_144652.3) | Silent (SNP) | VAF 28/106 reads (26%) | catalogued as rs767251174, COSV52685779; called by muse, mutect2, varscan2
